CPTAC case C3N-03617 — Skin — Nevi and Melanomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Nevi and Melanomas; Primary site: Skin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ddd99c12-5f7a-4240-a835-86971ac219c6

Demographics
Sex at birth: male; Race: white; Year of birth: 1944; Vital status: Alive; Country of birth: Ukraine.

Diagnoses (1)
1. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Skin of trunk; Age at diagnosis: 73.5 years (26,863 days); Year of diagnosis: 2018; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T4b; AJCC pathologic N: NX; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIC; Residual disease: R0; Last known disease status: Tumor free; Days to last known disease status: 348 days; Progression or recurrence: no; Days to last follow up: 348 days; Tumor focality: Multifocal; Ulceration indicator: Yes.
   Pathology details: Breslow thickness category: >4.0 mm; Greatest tumor dimension: 2 cm; Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 0; Lymphatic invasion present: No; Margin status: Uninvolved; Vascular invasion present: No.

Follow-up (1 entry)
- Days to follow up: 348 days; Disease response: Tumor Free.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-03617-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Trunk; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -5 days; Initial weight: 110 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-03617-23: Section location: Trunk; Percent tumor nuclei: 80; Percent necrosis: 5.
- Sample C3N-03617-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Trunk; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -5 days; Initial weight: 100 mg; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3N-03617-71: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -5 days; Method of sample procurement: Blood Draw.
